Gene-level copy-number profile of tumor specimen TCGA-14-3477-01A from TCGA case TCGA-14-3477, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 38.6 years (14,082 days).
Specimen TCGA-14-3477-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.668c25ce-be82-4a0e-9735-0d6ee8fd3248.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-14-3477-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/72535e51-04ac-4f77-b1ea-722acbe6a81b

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 201; copy number 3: 6,416; copy number 4: 9,879; copy number 5: 14,976; copy number 6: 17,610; copy number 7: 7,493; copy number 8: 2,423; copy number 9: 396; copy number 10: 246; copy number 11: 5; copy number 14: 8; copy number 16: 16; copy number 18: 22; copy number 29: 2; copy number 31: 34; copy number 43: 6; copy number 46: 18; copy number 49: 4; copy number 55: 40; copy number 68: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-14-3477-01A-01D-0911-01): tumor purity 0.92, ploidy 5.28, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 165 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:179,097,731–179,267,002, 6 genes, copy number 14: Y_RNA, AC076966.2, PIK3CA, AC076966.1, KCNMB3, LRRFIP1P1.
- chr4:52,252,820–54,376,752, 40 genes, copy number 55: AC097522.2, AC097522.1, RNU6-1252P, USP46, USP46-DT, AC104066.3, DANCR, LINC01618, MIR4449, AC104066.4, SNORA26, AC104066.2, ERVMER34-1, AC104066.1, Y_RNA, RASL11B, SCFD2, AC023154.1, RNU6-310P, FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1.
- chr4:57,490,808–59,180,414, 15 genes, copy number 68: AC013724.1, AC107396.1, AC093725.2, AC093725.1, AC104790.1, SRIP1, AC096725.1, LINC02494, AC019133.1, AC017091.1, LINC02619, LINC02429, AC097501.1, AC108517.2, AC108517.1.
- chr4:79,827,471–79,877,770, 2 genes, copy number 29: PCAT4, SNORA75.
- chr8:92,460,539–94,104,322, 34 genes, copy number 31: AC091096.1, AC104211.1, AC104211.3, FLJ46284, AC104211.2, AC117834.2, AC117834.1, TRIQK, IRF5P1, MIR8084, C8orf87, LINC00535, AC016885.1, AC016885.3, AC016885.2, RNA5SP274, ZNF317P1, CIBAR1, AC120053.1, AC010834.3, RBM12B, AC010834.1, RBM12B-AS1, AC010834.2, TMEM67, AC084346.1, MYL12AP1, PDP1, MIR378D2HG, MIR378D2, PSMA2P2, RPL34P18, AC105081.1, AP003351.1.
- chr8:142,657,460–142,736,927, 6 genes, copy number 43: JRK, PSCA, LY6K, LNCOC1, THEM6, AC108002.1.
- chr9:30,388,935–30,575,012, 2 genes, copy number 14: LINC01242, SLC4A1APP1.
- chr10:649,948–1,737,525, 16 genes, copy number 16 (within-gene range 7–16): PRR26, AL157709.1, LARP4B, AL359878.2, AL359878.1, GTPBP4, IDI2, IDI2-AS1, IDI1, WDR37, LINC00200, ADARB2, AL392083.2, AL392083.1, AL513304.1, ADARB2-AS1.
- chr10:22,208,814–23,038,523, 21 genes, copy number 18 (within-gene range 6–18): EBLN1, AL157831.2, PSME2P6, AL157831.3, AL158211.5, AL158211.1, RPL31P45, COMMD3, COMMD3-BMI1, BMI1, AL158211.4, AL158211.2, AL158211.3, SPAG6, AL513128.1, AL513128.3, AL513128.2, PIP4K2A, AL390318.1, RNU6-413P, ARMC3.
- chr10:22,997,255–22,997,358, 1 gene, copy number 18: RNA5SP304.
- chr12:10,551,266–10,613,609, 4 genes, copy number 49 (within-gene range 4–49): SLC25A39P2, LINC02446, KLRA1P, MAGOHB.
- chr17:30,316,333–30,672,789, 18 genes, copy number 46: TMIGD1, Y_RNA, RNU6-990P, CPD, GOSR1, ALOX12P1, AC011840.3, AC011840.5, TBC1D29P, AC011840.4, AC011840.2, KRT17P3, AC011840.1, AC005562.1, SMURF2P1, AC005562.2, SH3GL1P2, LRRC37BP1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
